Somatic mutation profile of tumor specimen TCGA-DX-A6YZ-01A (aliquot TCGA-DX-A6YZ-01A-12D-A351-09) from TCGA case TCGA-DX-A6YZ, project TCGA-SARC (Sarcoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Fibromyxosarcoma; Tissue or organ of origin: Connective, subcutaneous and other soft tissues of pelvis; Age at diagnosis: 59.9 years (21,886 days).
Specimen TCGA-DX-A6YZ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 66ec2400-4b5c-46c1-95b7-afdc8688aa49.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DX-A6YZ-10B (Blood Derived Normal), aliquot TCGA-DX-A6YZ-10B-01D-A351-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b22a87d4-4e5c-4f55-8146-ae29f5fec0f0

The open-access MAF lists 78 somatic variants for this specimen: 61 protein-altering or splice-affecting, 16 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 55, Silent 16, Nonsense Mutation 4, Translation Start Site 1, Splice Region 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACSM1 | c.1116G>A p.T372= | Splice Region (SNP) | VAF 24/54 reads (44%) | catalogued as rs765295558, COSV54633186; called by muse, mutect2, varscan2
- APOB | c.13043T>C p.L4348S | Missense Mutation (SNP) | VAF 5/70 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.951); catalogued as COSV99267455; called by muse, mutect2
- ARFGEF1 | c.2436C>A p.N812K | Missense Mutation (SNP) | VAF 5/44 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99144237; called by muse, mutect2, varscan2
- ARVCF | c.2077G>A p.G693S | Missense Mutation (SNP) | VAF 40/126 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.955); catalogued as COSV54269571; called by muse, mutect2, varscan2
- AURKB | c.442A>T p.R148W | Missense Mutation (SNP) | VAF 12/55 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.84); catalogued as COSV100298854; called by muse, mutect2, varscan2
- BSN | c.922C>G p.Q308E | Missense Mutation (SNP) | VAF 4/27 reads (15%) | SIFT tolerated (0.84); PolyPhen benign (0); catalogued as COSV99609589; called by muse, mutect2, varscan2
- CACFD1 | c.391A>T p.T131S | Missense Mutation (SNP) | VAF 27/81 reads (33%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.766); catalogued as rs782661209, COSV99390430; called by muse, mutect2, varscan2
- CACNA1H | c.332T>A p.M111K | Missense Mutation (SNP) | VAF 9/114 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.043); catalogued as COSV100673374; called by muse, mutect2
- CACNG5 | c.650A>T p.Y217F | Missense Mutation (SNP) | VAF 14/57 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.935); catalogued as COSV99400796; called by muse, mutect2, varscan2
- CCK | c.330G>T p.E110D | Missense Mutation (SNP) | VAF 20/95 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0.059); catalogued as COSV100589070; called by muse, mutect2, varscan2
- CIR1 | c.408T>A p.H136Q | Missense Mutation (SNP) | VAF 17/96 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100565078; called by muse, mutect2, varscan2
- COL21A1 | c.661A>G p.I221V | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.891); catalogued as COSV99779936; called by muse, mutect2
- COL4A5 | c.4025G>C p.G1342A | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100089461; called by muse, mutect2, varscan2
- CTNND2 | c.3536G>A p.R1179H | Missense Mutation (SNP) | VAF 13/102 reads (13%) | SIFT deleterious, low confidence (0.05); PolyPhen possibly damaging (0.572); catalogued as rs1341007475, COSV100474055; called by muse, mutect2, varscan2
- CWH43 | c.1135A>G p.K379E | Missense Mutation (SNP) | VAF 10/270 reads (4%) | SIFT tolerated (0.07); PolyPhen benign (0.385); catalogued as COSV99893947; called by muse, mutect2
- DAND5 | c.467C>T p.A156V | Missense Mutation (SNP) | VAF 18/62 reads (29%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as rs1425658043, COSV100397311; called by muse, mutect2, varscan2
- EPHA5 | c.205G>C p.V69L | Missense Mutation (SNP) | VAF 22/128 reads (17%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.447); catalogued as COSV99900809; called by muse, mutect2, varscan2
- EXD1 | c.655C>G p.L219V | Missense Mutation (SNP) | VAF 50/184 reads (27%) | SIFT tolerated (0.5); PolyPhen benign (0.022); catalogued as COSV100153805; called by muse, mutect2, varscan2
- FAT3 | c.10060G>A p.A3354T | Missense Mutation (SNP) | VAF 10/49 reads (20%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); catalogued as rs1214251877, COSV53150049; called by muse, mutect2, varscan2
- FGA | c.999C>G p.S333R | Missense Mutation (SNP) | VAF 17/91 reads (19%) | SIFT tolerated, low confidence (0.47); PolyPhen benign (0); catalogued as rs754059450, COSV100120662; called by muse, mutect2, varscan2
- GPN3 | c.69G>T p.M23I | Missense Mutation (SNP) | VAF 24/65 reads (37%) | SIFT tolerated (0.48); PolyPhen benign (0.015); catalogued as COSV99959943; called by muse, mutect2, varscan2
- HCAR3 | c.176G>A p.W59* | Nonsense Mutation (SNP) | VAF 8/153 reads (5%) | catalogued as COSV100811759; called by muse, mutect2
- IFNAR1 | c.23C>A p.A8E | Missense Mutation (SNP) | VAF 20/72 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.947); catalogued as COSV99531797; called by muse, mutect2, varscan2
- LILRB3 | c.1450C>T p.H484Y (on ENST00000346401; = p.H472Y on NM_006864.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/64 reads (13%) | SIFT tolerated (1); PolyPhen possibly damaging (0.596); catalogued as COSV99558335; called by muse, mutect2, varscan2
- LIPI | c.146G>A p.S49N | Missense Mutation (SNP) | VAF 7/92 reads (8%) | SIFT tolerated (0.68); PolyPhen benign (0.018); catalogued as COSV100753960; called by muse, mutect2
- LRRN1 | c.2T>A p.M1? | Translation Start Site (SNP) | VAF 14/67 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.888); catalogued as COSV100076540; called by muse, mutect2, varscan2
- NDUFA7 | c.16C>T p.R6C | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.877); catalogued as rs553849517, COSV100035606, COSV56847725; called by muse, varscan2
- NLRP12 | c.550G>A p.A184T | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT tolerated (0.25); PolyPhen benign (0.007); catalogued as rs766308091, COSV60757158; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NOS3 | c.158G>T p.S53I | Missense Mutation (SNP) | VAF 14/111 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as COSV99872065; called by muse, mutect2, varscan2
- NRXN1 | c.4054C>T p.L1352F | Missense Mutation (SNP) | VAF 11/70 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.658); catalogued as COSV100640631; called by muse, mutect2, varscan2
- NUCB2 | c.122A>G p.E41G | Missense Mutation (SNP) | VAF 8/76 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.001); catalogued as COSV100082941; called by muse, mutect2
- OR13F1 | c.364C>T p.R122W | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.931); catalogued as rs201311592, COSV58252861; called by muse, mutect2
- OR5H6 | c.344T>A p.V115E (on ENST00000642105; = p.V99E on NM_001005479.2) | Missense Mutation (SNP) | VAF 22/88 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.239); catalogued as COSV101051807; called by muse, mutect2, varscan2
- PCDHAC2 | c.716G>T p.G239V | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV99157343; called by muse, mutect2, varscan2
- PCSK5 | c.1497C>A p.N499K | Missense Mutation (SNP) | VAF 9/69 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.534); catalogued as COSV100950573, COSV65097009; called by muse, mutect2, varscan2
- PHF20L1 | c.2253C>A p.C751* | Nonsense Mutation (SNP) | VAF 12/64 reads (19%) | catalogued as COSV99621974; called by muse, mutect2, varscan2
- PI3 | c.331A>C p.M111L | Missense Mutation (SNP) | VAF 17/88 reads (19%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as COSV99714264; called by muse, mutect2, varscan2
- PIK3CB | c.425A>T p.D142V | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.852); catalogued as COSV100006014; called by muse, mutect2, varscan2
- PNPLA3 | c.997A>T p.K333* | Nonsense Mutation (SNP) | VAF 18/71 reads (25%) | catalogued as COSV99337283; called by muse, mutect2, varscan2
- PSG11 | c.627G>T p.K209N | Missense Mutation (SNP) | VAF 29/220 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.06); catalogued as rs142166158; called by muse, mutect2, varscan2
- PTPRC | c.1312G>T p.D438Y | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT tolerated (0.06); PolyPhen benign (0.226); catalogued as COSV100723054; called by muse, mutect2, varscan2
- RARS1 | c.1716G>A p.W572* | Nonsense Mutation (SNP) | VAF 6/84 reads (7%) | catalogued as COSV99199209; called by muse, mutect2
- RELN | c.6512A>T p.D2171V | Missense Mutation (SNP) | VAF 5/49 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100634678, COSV58986605; called by muse, mutect2, varscan2
- RSC1A1 | c.1151C>T p.T384I | Missense Mutation (SNP) | VAF 25/44 reads (57%) | SIFT tolerated (0.09); PolyPhen benign (0.007); catalogued as rs1418458233, COSV100197867; called by muse, mutect2, varscan2
- SBF2 | c.451T>C p.S151P | Missense Mutation (SNP) | VAF 15/47 reads (32%) | SIFT tolerated (0.64); PolyPhen benign (0.02); catalogued as COSV99815528; called by muse, mutect2, varscan2
- SLC2A13 | c.961C>A p.P321T | Missense Mutation (SNP) | VAF 23/113 reads (20%) | SIFT tolerated (0.25); PolyPhen benign (0.115); catalogued as COSV99787007; called by muse, mutect2, varscan2
- SLC4A9 | c.2666C>G p.T889R (on ENST00000507527 / NM_001258428.2; = p.T865R on NM_031467.3) | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99139707; called by muse, mutect2, varscan2
- SMC2 | c.2497C>T p.H833Y | Missense Mutation (SNP) | VAF 6/78 reads (8%) | SIFT tolerated (1); PolyPhen benign (0.028); catalogued as COSV99659570; called by muse, mutect2
- SPO11 | c.251A>T p.E84V | Missense Mutation (SNP) | VAF 15/138 reads (11%) | SIFT tolerated (0.14); PolyPhen benign (0.051); catalogued as COSV100625788, COSV61996363; called by muse, mutect2, varscan2
- TAS2R39 | c.922T>A p.S308T | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); catalogued as COSV101489418; called by muse, mutect2, varscan2
- TC2N | c.371A>C p.Y124S | Missense Mutation (SNP) | VAF 9/55 reads (16%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as COSV100563057; called by muse, mutect2, varscan2
- TELO2 | c.716C>G p.A239G | Missense Mutation (SNP) | VAF 4/68 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.079); catalogued as COSV99248650; called by muse, mutect2
- TFAP2D | c.710G>A p.R237H | Missense Mutation (SNP) | VAF 13/70 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs769871422, COSV50457626; called by muse, mutect2, varscan2
- TMEM67 | c.2810C>T p.A937V | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT tolerated (0.31); PolyPhen benign (0.193); catalogued as COSV100019788; called by muse, mutect2, varscan2
- TNC | c.887A>T p.E296V | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.521); catalogued as COSV100406163; called by muse, mutect2
- TTC21B | c.253C>T p.P85S | Missense Mutation (SNP) | VAF 13/55 reads (24%) | SIFT tolerated (0.52); PolyPhen benign (0.001); catalogued as COSV99692766; called by muse, mutect2, varscan2
- WFIKKN2 | c.1168G>A p.A390T | Missense Mutation (SNP) | VAF 9/65 reads (14%) | SIFT tolerated (0.12); PolyPhen benign (0.198); catalogued as rs777517936, COSV60957989; called by muse, mutect2, varscan2
- ZC3H14 | c.2048G>A p.R683H | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs1369427682, COSV99193220; called by muse, mutect2, varscan2
- ZNF831 | c.2741C>A p.A914E | Missense Mutation (SNP) | VAF 22/244 reads (9%) | SIFT tolerated (0.05); PolyPhen benign (0); catalogued as COSV100926215; called by muse, mutect2
- KLC2 | c.94C>T p.R32C | Missense Mutation (SNP) | VAF 4/51 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2
- TRAJ31 | c.56C>A p.P19H | Missense Mutation (SNP) | VAF 21/108 reads (19%) | called by muse, mutect2, varscan2
- ASIC5 | c.81A>G p.P27= | Silent (SNP) | VAF 16/83 reads (19%) | catalogued as COSV101539790; called by muse, mutect2, varscan2
- CKAP2L | c.1221C>T p.N407= | Silent (SNP) | VAF 12/55 reads (22%) | catalogued as COSV100198741; called by muse, mutect2, varscan2
- DNAH1 | c.7203G>C p.G2401= | Silent (SNP) | VAF 24/133 reads (18%) | catalogued as COSV101326882; called by muse, mutect2, varscan2
- FMNL2 | c.2916T>C p.P972= | Silent (SNP) | VAF 9/91 reads (10%) | catalogued as COSV99980593; called by muse, mutect2
- GCK | c.621G>T p.V207= | Silent (SNP) | VAF 15/44 reads (34%) | catalogued as COSV100357010; called by muse, mutect2, varscan2
- GRAMD1B | c.1092C>A p.V364= | Silent (SNP) | VAF 9/34 reads (26%) | catalogued as COSV100455149; called by muse, mutect2, varscan2
- KRR1 | c.381T>C p.V127= | Silent (SNP) | VAF 7/65 reads (11%) | catalogued as rs760241898, COSV99875849; called by muse, mutect2
- NCKIPSD | c.1372C>T p.L458= | Silent (SNP) | VAF 9/36 reads (25%) | catalogued as COSV99584202; called by muse, mutect2, varscan2
- NTN4 | c.495C>T p.S165= | Silent (SNP) | VAF 11/76 reads (14%) | catalogued as rs758912394, COSV100643860; called by muse, mutect2, varscan2
- PROX1 | c.147T>C p.G49= | Silent (SNP) | VAF 15/55 reads (27%) | catalogued as COSV99800104; called by muse, mutect2, varscan2
- PWWP3B | c.1125C>T p.D375= | Silent (SNP) | VAF 18/34 reads (53%) | catalogued as rs367590084, COSV61799131; called by muse, mutect2, varscan2
- RNF125 | c.624A>T p.I208= | Silent (SNP) | VAF 13/62 reads (21%) | catalogued as COSV99470615; called by muse, mutect2, varscan2
- SLC24A2 | c.1791T>C p.A597= | Silent (SNP) | VAF 6/34 reads (18%) | catalogued as COSV99647312; called by muse, mutect2, varscan2
- SOX7 | c.255G>A p.A85= | Silent (SNP) | VAF 8/41 reads (20%) | catalogued as rs368097716; called by muse, mutect2, varscan2
- TBL1Y | c.102C>T p.I34= | Silent (SNP) | VAF 14/182 reads (8%) | catalogued as COSV100667343; called by muse, mutect2
- TTN | c.12954G>T p.V4318= (on ENST00000591111; = p.V4272= on NM_003319.4) | Silent (SNP) | VAF 12/68 reads (18%) | catalogued as rs1303608409, COSV100626653, COSV59913413; called by muse, mutect2, varscan2
- ZNF665 | c.-53-9202T>C | Intron (SNP) | VAF 17/163 reads (10%) | catalogued as COSV101128731; called by muse, mutect2, varscan2
